Somatic mutation profile of tumor specimen TCGA-FS-A4F2-06A (aliquot TCGA-FS-A4F2-06A-11D-A24R-08) from TCGA case TCGA-FS-A4F2, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 50.3 years (18,371 days).
Specimen TCGA-FS-A4F2-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d13db23-0aca-4d9d-b372-b35fffa4182d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A4F2-10A (Blood Derived Normal), aliquot TCGA-FS-A4F2-10A-01D-A24R-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd8138f1-8220-4e84-9ea0-1df5af7535ad

The open-access MAF lists 833 somatic variants for this specimen: 555 protein-altering or splice-affecting, 257 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 505, Silent 257, Nonsense Mutation 23, Splice Site 14, Intron 11, Splice Region 9, RNA 4, 5'UTR 3, Frame Shift Del 2, 3'UTR 2, In Frame Del 1, 3'Flank 1.

Variants (750 of 833; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1267G>T p.G423* (on ENST00000281708 / NM_001349798.2; = p.G343* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 138/190 reads (73%) | hotspot (GDC flag); catalogued as COSV55896970, COSV55902795, COSV55936902; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 164/260 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.3316C>T p.R1106* | Nonsense Mutation (SNP) | VAF 34/103 reads (33%) | catalogued as rs202033121, CM094636; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 59/69 reads (86%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1181-1G>A p.X394_splice (on ENST00000272895 / NM_173076.3; = p.X76_splice on NM_015657.3) | Splice Site (SNP) | VAF 9/64 reads (14%) | catalogued as COSV55970075; called by muse, mutect2, varscan2
- ABCA4 | c.3845C>T p.S1282L | Missense Mutation (SNP) | VAF 158/258 reads (61%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as CD015124; called by muse, mutect2, varscan2
- ABCA4 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 68/128 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV64671275; called by muse, mutect2, varscan2
- ABCB11 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV55597331; called by muse, mutect2, varscan2
- ABCB5 | c.1838G>A p.R613Q (on ENST00000404938 / NM_001163941.2; = p.R168Q on NM_178559.6) | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1187222290, COSV51706928; called by muse, mutect2, varscan2
- ABCB7 | c.1675C>T p.H559Y (on ENST00000373394 / NM_001271696.3; = p.H560Y on NM_004299.6) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1421273867; called by muse, mutect2, varscan2
- ABCG8 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55395459; called by muse, mutect2, varscan2
- ACCSL | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 127/388 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780298251; called by muse, mutect2, varscan2
- ADAMTS8 | c.1752G>A p.G584= | Splice Region (SNP) | VAF 50/103 reads (49%) | catalogued as COSV57291945; called by muse, mutect2, varscan2
- ADCY4 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1170453617; called by muse, mutect2, varscan2
- ADGRL2 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs759899683, COSV54681134; called by muse, mutect2, varscan2
- ADGRV1 | c.14605C>A p.L4869I | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV101315430; called by muse, mutect2, varscan2
- AFF3 | c.2294C>T p.S765F | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57839331; called by muse, mutect2, varscan2
- AGFG1 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs901070431; called by muse, mutect2, varscan2
- AGTR2 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100903642; called by muse, mutect2, varscan2
- AHNAK | c.15139C>T p.P5047S | Missense Mutation (SNP) | VAF 126/303 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57209845; called by muse, mutect2, varscan2
- AKAP9 | c.9784G>A p.D3262N (on ENST00000359028; = p.D3238N on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.592); catalogued as COSV62353080; called by muse, mutect2, varscan2
- AKR1C3 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1330490806; called by muse, mutect2, varscan2
- AMPD1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 61/99 reads (62%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV62417844; called by muse, mutect2, varscan2
- ANK2 | c.11197G>A p.G3733R | Missense Mutation (SNP) | VAF 77/101 reads (76%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.951); catalogued as COSV52172761; called by muse, mutect2, varscan2
- ANK3 | c.10309C>T p.Q3437* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as COSV55049044; called by muse, mutect2, varscan2
- ANKRD30A | c.3307G>A p.E1103K (on ENST00000611781; = p.E1047K on NM_052997.2) | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs267602484, COSV64608616; called by muse, mutect2, varscan2
- ARAP2 | c.4655C>T p.S1552L | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs1237277466; called by muse, mutect2, varscan2
- ARHGDIB | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56762315; called by muse, mutect2, varscan2
- ARID2 | c.2455C>T p.Q819* | Nonsense Mutation (SNP) | VAF 57/85 reads (67%) | catalogued as COSV57594531; called by muse, mutect2, varscan2
- ARMH4 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 90/121 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs761546306, COSV50771714, COSV50778649; called by muse, mutect2, varscan2
- ARNT2 | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 67/149 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as rs1227421929; called by muse, mutect2, varscan2
- ASMTL | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV67244674; called by muse, mutect2, varscan2
- ASXL3 | c.4603C>T p.H1535Y | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); catalogued as COSV52465711; called by muse, mutect2, varscan2
- ATP1B4 | c.473C>T p.P158L (on ENST00000218008 / NM_001142447.3; = p.P154L on NM_012069.5) | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475218037; called by muse, mutect2, varscan2
- ATP8B2 | c.3013C>T p.P1005S (on ENST00000672630; = p.P972S on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/96 reads (82%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs1471642319; called by muse, mutect2, varscan2
- ATRX | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 93/211 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV64873757, COSV64875914; called by muse, mutect2, varscan2
- ATXN7L2 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.979); catalogued as COSV63992104; called by muse, mutect2, varscan2
- BCLAF1 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); catalogued as rs758231115, COSV62144950; called by muse, mutect2, varscan2
- C1S | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.47); catalogued as rs781818479, COSV61072007; called by muse, mutect2, varscan2
- C2orf78 | c.1100C>T p.T367I | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.876); catalogued as rs1313848693; called by muse, mutect2, varscan2
- C8orf34 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs377632950, COSV61396559; called by muse, mutect2, varscan2
- C8orf34 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV57410813; called by muse, mutect2, varscan2
- CAPN6 | c.1104G>A p.M368I | Missense Mutation (SNP) | VAF 202/503 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV60697428; called by muse, mutect2, varscan2
- CASR | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV56134140; called by muse, mutect2, varscan2
- CBLL1 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 88/217 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.146); catalogued as COSV56028334; called by muse, mutect2, varscan2
- CBLL2 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 111/264 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV60368656; called by muse, mutect2, varscan2
- CC2D1B | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs745898780; called by muse, mutect2, varscan2
- CCR3 | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV62463435; called by muse, mutect2, varscan2
- CDCP2 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61285876; called by muse, mutect2, varscan2
- CDK14 | c.688C>T p.P230S (on ENST00000380050 / NM_001287135.2; = p.P212S on NM_012395.3) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.98); catalogued as COSV99726774; called by muse, mutect2, varscan2
- CDK5RAP1 | c.976G>A p.E326K (on ENST00000357886 / NM_001365728.1; = p.E312K on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV100212265, COSV59426597; called by muse, mutect2, varscan2
- CEP112 | c.2711G>A p.R904Q (on ENST00000392769 / NM_001353127.1; = p.R160Q on NM_001037325.3) | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.12); PolyPhen benign (0.314); catalogued as rs375574894, COSV100439458; called by muse, mutect2, varscan2
- CFAP221 | c.1780A>C p.K594Q | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as COSV99733324; called by muse, varscan2
- CFHR2 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 94/116 reads (81%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV66382454; called by muse, mutect2, varscan2
- CGNL1 | c.3676G>A p.E1226K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1239664065, COSV55564726; called by muse, mutect2, varscan2
- CLGN | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs564584207, COSV57774139; called by muse, mutect2, varscan2
- CNOT1 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV57772303; called by muse, mutect2, varscan2
- CNTN6 | c.1337G>A p.G446E | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs1359807586; called by muse, mutect2, varscan2
- CNTNAP2 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV62142627, COSV62264874; called by muse, mutect2, varscan2
- COL5A1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1274412604; called by muse, mutect2, varscan2
- COL5A1 | c.3065C>T p.P1022L | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV65672997; called by muse, mutect2, varscan2
- COL5A2 | c.567+1G>A p.X189_splice | Splice Site (SNP) | VAF 7/15 reads (47%) | catalogued as COSV66408492; called by muse, mutect2, varscan2
- COL7A1 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780113498, COSV60392078; called by muse, mutect2, varscan2
- COL9A1 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 137/176 reads (78%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs780899445, COSV61831236; called by muse, mutect2, varscan2
- CORO7 | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1349827960; called by muse, mutect2, varscan2
- CPNE9 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs761256055; called by muse, mutect2, varscan2
- CSMD2 | c.4522C>T p.L1508F | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as rs1440077090; called by muse, mutect2, varscan2
- CSMD3 | c.10717G>A p.E3573K (on ENST00000297405 / NM_001363185.1; = p.E3404K on NM_052900.3) | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV99848226; called by muse, mutect2, varscan2
- CYFIP2 | c.2702G>A p.R901Q (on ENST00000616178 / NM_001291722.2; = p.R876Q on NM_014376.4) | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV56636493; called by muse, mutect2, varscan2
- CYLC2 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated (0.51); PolyPhen benign (0.396); catalogued as rs1564097672, COSV66337948; called by muse, mutect2, varscan2
- CYP4A11 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 87/145 reads (60%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs141891892; called by muse, mutect2, varscan2
- DCC | c.4144G>C p.A1382P | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV71434601; called by muse, mutect2, varscan2
- DLC1 | c.2483C>T p.S828F (on ENST00000276297 / NM_001348081.2; = p.S391F on NM_006094.5) | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV52291237, COSV52292699; called by muse, mutect2, varscan2
- DMBT1 | c.6370C>T p.P2124S (on ENST00000338354 / NM_001377530.1; = p.P1367S on NM_004406.3) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.113); catalogued as rs867737779, COSV57544883; called by muse, mutect2, varscan2
- DNAH10 | c.1422-1G>A p.X474_splice (on ENST00000409039; = p.X413_splice on NM_207437.3) | Splice Site (SNP) | VAF 10/15 reads (67%) | catalogued as rs201134504; called by muse, mutect2, varscan2
- DNAH11 | c.1010T>A p.L337H | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV60960178; called by muse, mutect2, varscan2
- DNAH17 | c.10793C>T p.S3598L | Missense Mutation (SNP) | VAF 51/60 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs537085638, COSV67757842; called by muse, mutect2, varscan2
- DNAH2 | c.10373C>T p.S3458F | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV66725222; called by muse, mutect2, varscan2
- DNAH9 | c.5701G>A p.D1901N | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV52380702, COSV99303159; called by muse, mutect2, varscan2
- DNAJC22 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 66/91 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs772597996; called by muse, mutect2, varscan2
- DOCK2 | c.3391G>A p.E1131K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1360509769, COSV56947114, COSV56971412; called by muse, mutect2, varscan2
- DOCK8 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs564090348; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPP10 | c.1592G>A p.G531E | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1387126117, COSV59689642; called by muse, mutect2, varscan2
- DPP4 | c.1925C>T p.S642L | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as rs200839327, COSV100859078; called by muse, mutect2, varscan2
- DSC3 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1335896856, COSV64574902; called by muse, mutect2, varscan2
- DSCAM | c.3706G>A p.E1236K | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.94); catalogued as rs1471305566, COSV68022769; called by muse, mutect2, varscan2
- DSCAM | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as rs267606128, COSV68029375; called by muse, mutect2, varscan2
- DSG1 | c.3053C>T p.S1018F | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57137053; called by muse, mutect2, varscan2
- DSG4 | c.1072C>T p.H358Y | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1408952331, COSV100355729; called by muse, mutect2, varscan2
- EFCAB12 | c.1199A>G p.K400R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as rs938809691, COSV58176416; called by muse, mutect2
- ELMOD1 | c.162C>T p.I54= | Splice Region (SNP) | VAF 7/17 reads (41%) | catalogued as rs778201960, COSV56190562; called by muse, mutect2, varscan2
- ERBB4 | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs267599191, COSV53505317; called by muse, varscan2
- EZHIP | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs1437738052; called by muse, mutect2
- F10 | c.867G>A p.G289= | Splice Region (SNP) | VAF 72/195 reads (37%) | catalogued as rs546723477, COSV65023250; called by muse, mutect2, varscan2
- F13B | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 64/78 reads (82%) | SIFT tolerated (0.65); PolyPhen benign (0.049); catalogued as rs533288735, COSV66374683; called by muse, mutect2, varscan2
- F2RL1 | c.795G>A p.M265I | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV56996146; called by muse, mutect2, varscan2
- FAM47A | c.1669C>T p.H557Y | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.187); catalogued as COSV60493956; called by muse, varscan2
- FAT3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53073120; called by muse, mutect2, varscan2
- FAT3 | c.5548C>T p.H1850Y | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV53093612; called by muse, mutect2, varscan2
- FAT4 | c.10031G>A p.R3344Q | Missense Mutation (SNP) | VAF 74/103 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs769028469, COSV58676528; called by muse, mutect2, varscan2
- FBN3 | c.3610C>T p.P1204S | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs770030545, COSV54468227; called by muse, mutect2, varscan2
- FBXO24 | c.997C>T p.R333C (on ENST00000241071 / NM_033506.3; = p.R371C on NM_012172.5) | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs779307679, COSV53824030; called by muse, mutect2, varscan2
- FERMT1 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.61); catalogued as rs1323658510, COSV54090277; called by muse, mutect2, varscan2
- FLG2 | c.4060G>A p.E1354K | Missense Mutation (SNP) | VAF 219/276 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV66171473; called by muse, mutect2, varscan2
- FOXR2 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV100189606; called by muse, mutect2, varscan2
- FRMD8 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58214432; called by muse, mutect2, varscan2
- FRY | c.7828C>T p.L2610F | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs375510471, COSV100969854; called by muse, mutect2, varscan2
- GABRA2 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as COSV62913736; called by muse, mutect2, varscan2
- GABRE | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT tolerated (0.95); PolyPhen benign (0.023); catalogued as rs866441978, COSV64819336; called by muse, mutect2, varscan2
- GALNT17 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774457548, COSV61148627; called by muse, mutect2, varscan2
- GIMAP4 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV55435247; called by muse, mutect2, varscan2
- GIMAP6 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 180/550 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61035018; called by muse, mutect2, varscan2
- GIMAP8 | c.1487C>T p.S496F | Missense Mutation (SNP) | VAF 75/137 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs753699589, COSV56231934; called by muse, mutect2, varscan2
- GLB1L2 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 104/227 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs998020488; called by muse, mutect2, varscan2
- GLRA2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 50/112 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); catalogued as COSV54347512; called by muse, mutect2, varscan2
- GNMT | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 72/115 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs755100354, COSV55102134; called by muse, mutect2, varscan2
- GPR179 | c.4093G>A p.E1365K (on ENST00000621958; = p.E1364K on NM_001004334.4) | Missense Mutation (SNP) | VAF 55/72 reads (76%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs765007436; called by muse, mutect2, varscan2
- GPR78 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs770418487, COSV66762564; called by muse, mutect2, varscan2
- GZMA | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142259151; called by muse, mutect2, varscan2
- HAL | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 92/134 reads (69%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs764306975; called by muse, mutect2, varscan2
- HCAR1 | c.132G>A p.M44I | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV63674564; called by muse, mutect2, varscan2
- HNRNPH2 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 138/379 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.053); catalogued as COSV57266875; called by muse, mutect2, varscan2
- HTR2A | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.42); catalogued as rs1428173433, COSV66326797; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.397); catalogued as rs1380623544; called by muse, mutect2, varscan2
- IGHV5-51 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs549160451; called by muse, mutect2, varscan2
- IGLV4-3 | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs1470475131; called by muse, mutect2, varscan2
- IL18RAP | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs752348672, COSV51824160; called by muse, mutect2, varscan2
- IL2RB | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV53425048; called by muse, mutect2, varscan2
- IMPG1 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs761693136, COSV64054340; called by muse, mutect2, varscan2
- IMPG2 | c.3482C>T p.P1161L | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs768189143; called by muse, mutect2, varscan2
- IQGAP2 | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as rs749399514; called by muse, mutect2, varscan2
- IRAG1 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.197); catalogued as COSV70212312; called by muse, mutect2, varscan2
- JARID2 | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs1377188510, COSV59189927; called by muse, mutect2, varscan2
- KANK4 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 110/187 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777904139; called by muse, mutect2, varscan2
- KIF9 | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs370497011; called by muse, mutect2, varscan2
- KLHL30 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs904204914; called by muse, mutect2, varscan2
- KLRC4 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.093); catalogued as rs762665540; called by muse, mutect2, varscan2
- KMT2C | c.2509C>T p.P837S | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs566541905, COSV51311624, COSV51466784; called by muse, mutect2, varscan2
- KRT1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 42/67 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs765763232, COSV52868587; called by muse, mutect2, varscan2
- KRT84 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 82/121 reads (68%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1176735347, COSV57773089; called by muse, mutect2, varscan2
- KRTAP26-1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 142/359 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as rs771669784, COSV62129360; called by muse, mutect2, varscan2
- LAMP1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.323); catalogued as rs1336868934; called by muse, mutect2, varscan2
- LGI1 | c.1424G>A p.G475E | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65057784; called by muse, mutect2, varscan2
- LMF1 | c.1660C>T p.P554S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as rs1407660766; called by mutect2, varscan2
- LRCH1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs775023587; called by muse, mutect2, varscan2
- LRRC15 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs150995251, COSV61651190; called by muse, mutect2, varscan2
- LRRC49 | c.1932G>A p.M644I | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as rs267604306; called by muse, mutect2, varscan2
- LRRC4C | c.750G>A p.M250I | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1245478778, COSV53423667; called by muse, mutect2, varscan2
- MACF1 | c.11291C>T p.S3764L (on ENST00000372915; = p.S1697L on NM_012090.5) | Missense Mutation (SNP) | VAF 50/86 reads (58%) | catalogued as rs758126025; called by muse, mutect2, varscan2
- MAGEC1 | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 324/1138 reads (28%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.944); catalogued as COSV53569627; called by muse, mutect2, varscan2
- MAL2 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 82/215 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745631374, COSV52661872; called by muse, mutect2, varscan2
- MAP7D2 | c.347G>A p.R116K | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV65527451; called by muse, mutect2, varscan2
- MARCO | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100503329; called by muse, mutect2, varscan2
- MC3R | c.264T>G p.S88R | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1487846955; called by muse, mutect2, varscan2
- MDN1 | c.2576C>T p.S859F | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65524157; called by muse, mutect2, varscan2
- METTL21C | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs547467269, COSV57432273; called by muse, mutect2, varscan2
- MGAM | c.3200C>T p.P1067L | Missense Mutation (SNP) | VAF 114/227 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs372065250; called by muse, mutect2, varscan2
- MPPED1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV68837356; called by muse, mutect2, varscan2
- MROH8 | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.444); catalogued as COSV99457623; called by muse, mutect2, varscan2
- MTFR1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758784637; called by muse, mutect2, varscan2
- MUC16 | c.19366T>A p.S6456T | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.029); catalogued as COSV101200283; called by muse, varscan2
- MUC16 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs763691043, COSV67448892; called by muse, mutect2, varscan2
- MUC17 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 163/455 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV100073255; called by muse, mutect2, varscan2
- MUC17 | c.9103G>A p.G3035S | Missense Mutation (SNP) | VAF 304/783 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.258); catalogued as rs780171016, COSV60285581; called by muse, mutect2, varscan2
- MXRA5 | c.7636G>A p.D2546N | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs778756027; called by muse, mutect2, varscan2
- MYL1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs753537507; called by muse, mutect2, varscan2
- MYO3B | c.396G>A p.M132I | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58702249, COSV58712583; called by muse, mutect2, varscan2
- MYO5B | c.2245C>T p.R749* | Nonsense Mutation (SNP) | VAF 23/71 reads (32%) | catalogued as rs775529538, CM111504, COSV53211871; called by muse, mutect2, varscan2
- MYOM3 | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759137598, COSV58390934; called by muse, mutect2, varscan2
- MYT1L | c.2761C>T p.H921Y | Missense Mutation (SNP) | VAF 56/80 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV67717769; called by muse, mutect2, varscan2
- NEBL | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs1372983158, COSV65805079; called by muse, mutect2
- NEIL2 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1435980693, COSV99462244; called by muse, mutect2, varscan2
- NETO1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 78/183 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as rs1395330447, COSV55006087, COSV55012049; called by muse, mutect2, varscan2
- NIBAN3 | c.1827G>A p.W609* | Nonsense Mutation (SNP) | VAF 59/158 reads (37%) | catalogued as COSV56312425; called by muse, mutect2, varscan2
- NIPSNAP3B | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 50/77 reads (65%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs527249516; called by muse, mutect2, varscan2
- NLRP11 | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 58/80 reads (73%) | SIFT tolerated (0.7); PolyPhen benign (0.082); catalogued as COSV64088311; called by muse, mutect2, varscan2
- NLRP5 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1369528449; called by muse, mutect2, varscan2
- NRG1 | c.878C>T p.A293V (on ENST00000405005 / NM_013964.5; = p.A298V on NM_013956.5) | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs1183676405; called by muse, mutect2, varscan2
- NUTM2A | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as rs567830933; called by muse, mutect2, varscan2
- OBSCN | c.12190C>T p.R4064C | Missense Mutation (SNP) | VAF 56/77 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs952042125, COSV52742967; called by muse, mutect2, varscan2
- OR10R2 | c.924G>A p.M308I | Missense Mutation (SNP) | VAF 63/76 reads (83%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100936749; called by muse, mutect2, varscan2
- OR10W1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as rs866798099, COSV101223799; called by muse, mutect2, varscan2
- OR1M1 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs765053649, COSV70036933; called by muse, mutect2, varscan2
- OR1S2 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 79/236 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100224178; called by muse, mutect2, varscan2
- OR2D2 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.059); catalogued as rs267603156, COSV55056623; called by muse, mutect2, varscan2
- OR51A4 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV66749489; called by muse, mutect2, varscan2
- OR51B6 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs867826712; called by muse, varscan2
- OR51M1 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 131/360 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs866442558, COSV60785779; called by muse, mutect2, varscan2
- OR5H14 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 78/196 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV101454343, COSV71193561; called by muse, mutect2, varscan2
- OR6C3 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 51/76 reads (67%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.033); catalogued as COSV65571070; called by muse, mutect2, varscan2
- OR9A2 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100628305; called by muse, mutect2, varscan2
- PACRGL | c.504C>T p.V168= | Splice Region (SNP) | VAF 40/86 reads (47%) | catalogued as COSV54843061; called by muse, mutect2, varscan2
- PCDH19 | c.2324C>T p.S775L (on ENST00000373034 / NM_001184880.2; = p.S728L on NM_020766.3) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV55267482; called by muse, mutect2, varscan2
- PCDHA2 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as rs1210282107; called by muse, mutect2, varscan2
- PCDHA4 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); catalogued as COSV63538929; called by muse, mutect2, varscan2
- PCDHB9 | c.2194T>A p.F732I | Missense Mutation (SNP) | VAF 69/321 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.801); catalogued as rs782702601; called by muse, mutect2, varscan2
- PDZRN4 | c.1129G>A p.E377K (on ENST00000402685 / NM_001164595.2; = p.E119K on NM_013377.4) | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV54203500; called by muse, mutect2, varscan2
- PEG3 | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as rs1454776339; called by muse, mutect2, varscan2
- PEX5L | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs1560513158; called by muse, mutect2, varscan2
- PFKFB1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 88/249 reads (35%) | PolyPhen probably damaging (0.993); catalogued as COSV66628432; called by muse, mutect2, varscan2
- PKM | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV58786908; called by muse, mutect2, varscan2
- PLCE1 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs201512392, COSV53343117; called by muse, mutect2, varscan2
- POLQ | c.2903C>T p.S968F | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs768265300; called by muse, mutect2, varscan2
- POM121L12 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.798); catalogued as rs746175412, COSV68692799; called by muse, mutect2, varscan2
- PPP1R3A | c.2060G>A p.G687E | Missense Mutation (SNP) | VAF 128/344 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745649404, COSV52877132; called by muse, mutect2, varscan2
- PRDM16 | c.677-1G>A p.X226_splice | Splice Site (SNP) | VAF 43/73 reads (59%) | catalogued as COSV54595208; called by muse, mutect2, varscan2
- PROM2 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs144977181; called by muse, mutect2, varscan2
- PRRC2B | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs910041922; called by muse, mutect2, varscan2
- PTPRN2 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs768772921, COSV67029090; called by muse, mutect2, varscan2
- PYGL | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 54/72 reads (75%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV53585526; called by muse, mutect2, varscan2
- RAI2 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs1253920049, COSV58963641; called by muse, mutect2, varscan2
- RBM46 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 55/72 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55979947; called by muse, mutect2, varscan2
- RNF148 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 271/539 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as COSV57349680; called by muse, mutect2, varscan2
- RNF152 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.011); catalogued as rs775408371; called by muse, mutect2, varscan2
- ROS1 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as rs745980825, COSV63856085; called by muse, mutect2, varscan2
- RTP5 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs747100378, COSV58320257; called by muse, mutect2, varscan2
- RYR1 | c.3292G>A p.E1098K | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.459); catalogued as COSV62113892; called by muse, mutect2, varscan2
- RYR2 | c.11200C>T p.R3734C | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1060500150; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD9 | c.4759G>A p.E1587K | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV66074622; called by muse, mutect2, varscan2
- SATL1 | c.500G>A p.R167Q (on ENST00000395409; = p.R354Q on NM_001012980.2) | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs1324962730, COSV60577618; called by muse, mutect2, varscan2
- SCN1A | c.4533G>A p.M1511I (on ENST00000303395 / NM_001202435.3; = p.M1500I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57688264; called by muse, mutect2, varscan2
- SCUBE1 | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV62613883; called by muse, mutect2, varscan2
- SERPINA7 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.097); catalogued as COSV59665225; called by muse, mutect2, varscan2
- SERPINB3 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 95/209 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs868056621, COSV52190082, COSV99033279, COSV99379872; called by muse, mutect2, varscan2
- SI | c.1480C>T p.H494Y | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as COSV52297842; called by muse, mutect2, varscan2
- SI | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52274874; called by muse, mutect2, varscan2
- SLC12A3 | c.1095+1G>A p.X365_splice | Splice Site (SNP) | VAF 15/59 reads (25%) | catalogued as CS116986, CS116987; called by muse, mutect2, varscan2
- SLC16A14 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as rs201868521, COSV54616755; called by muse, mutect2, varscan2
- SLC22A25 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0.036); catalogued as rs769627276; called by muse, mutect2
- SLC35F4 | c.1108G>A p.G370S (on ENST00000339762 / NM_001352015.2; = p.G334S on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.45); catalogued as rs1207682744, COSV60265083; called by muse, mutect2, varscan2
- SLC39A10 | c.1993G>A p.G665R | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62769677; called by muse, mutect2, varscan2
- SLC44A5 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs749152541, COSV63764550; called by muse, mutect2, varscan2
- SLC5A5 | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99715102; called by muse, mutect2, varscan2
- SLC5A8 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101610624; called by muse, mutect2, varscan2
- SLC6A17 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416185596; called by muse, mutect2, varscan2
- SLC8A3 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63526615; called by muse, mutect2, varscan2
- SLIT3 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV60608641; called by muse, mutect2, varscan2
- SMOC1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 49/75 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs749505789, COSV62760239; called by muse, mutect2, varscan2
- SORCS3 | c.1684G>A p.G562R | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100865379; called by muse, mutect2, varscan2
- SPHKAP | c.4468G>A p.D1490N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs1384159842; called by muse, mutect2, varscan2
- SPHKAP | c.3542C>T p.P1181L | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as rs142006339; called by muse, mutect2, varscan2
- SPPL2B | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs375876911, COSV101194695; called by muse, mutect2, varscan2
- SRRM2 | c.4418C>T p.P1473L | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as rs1437643593; called by muse, mutect2, varscan2
- ST7 | c.58T>C p.W20R | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as rs1294460445; called by muse, mutect2, varscan2
- STON2 | c.2358G>A p.M786I (on ENST00000649389 / NM_001366849.2; = p.M729I on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/135 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs773220968; called by muse, mutect2, varscan2
- STRIP2 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99973427; called by muse, mutect2, varscan2
- STXBP3 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758784567, COSV100893954; called by muse, mutect2, varscan2
- STYK1 | c.835C>G p.R279G | Missense Mutation (SNP) | VAF 55/234 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as rs140055345; called by muse, mutect2, varscan2
- SULT1C3 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs144109255; called by muse, mutect2, varscan2
- SVEP1 | c.5441C>T p.S1814L | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); catalogued as rs571724898, COSV52837977; called by muse, mutect2, varscan2
- SYP | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs782810430, COSV54295798; called by muse, mutect2, varscan2
- SZT2 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368761999, COSV60290526; called by muse, mutect2, varscan2
- TAS2R60 | c.428G>A p.W143* | Nonsense Mutation (SNP) | VAF 137/278 reads (49%) | catalogued as COSV60330214; called by muse, mutect2, varscan2
- TAS2R60 | c.429G>A p.W143* | Nonsense Mutation (SNP) | VAF 138/275 reads (50%) | catalogued as rs149539350, COSV60331045; called by muse, mutect2, varscan2
- TESK2 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 84/161 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs748458464, COSV59157372; called by muse, mutect2, varscan2
- TFF1 | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1269954074; called by muse, mutect2, varscan2
- THEMIS | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100965201; called by muse, mutect2, varscan2
- THSD7B | c.2267G>A p.G756E | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as rs973091320, COSV55677134; called by muse, mutect2, varscan2
- TLR7 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.787); catalogued as rs868177091, COSV66124215; called by muse, mutect2, varscan2
- TMEM52B | c.530G>A p.R177Q (on ENST00000381923 / NM_001079815.1; = p.R157Q on NM_153022.4) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs1020176951, COSV53727450; called by muse, mutect2, varscan2
- TOM1 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs201384522; called by muse, mutect2, varscan2
- TOPBP1 | c.3379C>T p.R1127C | Missense Mutation (SNP) | VAF 92/181 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs758622720; called by muse, mutect2, varscan2
- TPO | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868428082, COSV104399692, COSV61107691; called by muse, mutect2
- TRAV9-2 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.534); catalogued as rs756911757; called by muse, mutect2, varscan2
- TRIM22 | c.300del p.H100Qfs*34 | Frame Shift Del (DEL) | VAF 36/102 reads (35%) | catalogued as COSV66090468; called by mutect2, varscan2
- TRIM22 | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV101181459; called by mutect2, varscan2
- TRPC4 | c.2267G>A p.G756E (on ENST00000379705 / NM_016179.4; = p.G761E on NM_003306.3) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.372); catalogued as COSV58992874; called by muse, mutect2, varscan2
- TRPM2 | c.2464C>T p.Q822* | Nonsense Mutation (SNP) | VAF 154/404 reads (38%) | catalogued as rs141737487, COSV55974184; called by muse, mutect2, varscan2
- TSGA10IP | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.647); catalogued as COSV73245284; called by muse, mutect2, varscan2
- TSGA13 | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.003); catalogued as rs1554465577; called by muse, mutect2, varscan2
- TTBK1 | c.2875G>A p.E959K | Missense Mutation (SNP) | VAF 114/175 reads (65%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.028); catalogued as rs775943513; called by muse, mutect2, varscan2
- TTLL4 | c.3086C>T p.S1029F | Missense Mutation (SNP) | VAF 70/121 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV51440368; called by muse, mutect2, varscan2
- UGT1A7 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60830276; called by muse, mutect2, varscan2
- UNC13A | c.2229G>T p.W743C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53199457; called by muse, mutect2, varscan2
- USP28 | c.3092C>T p.P1031L | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99136776; called by muse, mutect2, varscan2
- UTP6 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs146623373; called by muse, mutect2, varscan2
- VAV3 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs368084503; called by muse, mutect2, varscan2
- VPS54 | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 77/163 reads (47%) | catalogued as COSV55439554; called by muse, mutect2, varscan2
- VWF | c.3805G>A p.D1269N | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs770786924, COSV54612216; called by muse, mutect2, varscan2
- WASF3 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs767056498; called by muse, mutect2, varscan2
- WASF3 | c.1345C>T p.R449* | Nonsense Mutation (SNP) | VAF 39/95 reads (41%) | catalogued as rs1465923845, COSV58963978; called by muse, mutect2, varscan2
- WEE2 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV66879006; called by muse, mutect2, varscan2
- WRN | c.4217G>A p.R1406Q | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs758132889; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZKSCAN2 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100048265; called by muse, mutect2, varscan2
- ZNF222 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 58/72 reads (81%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV51828924; called by muse, mutect2, varscan2
- ZNF331 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 60/87 reads (69%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99466796; called by muse, mutect2, varscan2
- ZNF423 | c.3646G>A p.D1216N (on ENST00000563137 / NM_001379286.1; = p.D1208N on NM_015069.4) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV99282800; called by muse, mutect2, varscan2
- ZNF560 | c.158-1G>A p.X53_splice | Splice Site (SNP) | VAF 72/184 reads (39%) | catalogued as COSV56871905; called by muse, mutect2, varscan2
- ZNF804A | c.2737G>A p.D913N | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV56448503, COSV56464562; called by muse, mutect2, varscan2
- ABCA13 | c.11205G>A p.G3735= | Splice Region (SNP) | VAF 39/81 reads (48%) | called by muse, mutect2, varscan2
- ABCB5 | c.2260-1G>A p.X754_splice (on ENST00000404938 / NM_001163941.2; = p.X309_splice on NM_178559.6) | Splice Site (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- ABCB5 | c.2260G>A p.G754R (on ENST00000404938 / NM_001163941.2; = p.G309R on NM_178559.6) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ACP3 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 107/208 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ADAM12 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 64/118 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- ADAMDEC1 | c.1271G>A p.G424E | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADARB2 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.955-1G>A p.X319_splice | Splice Site (SNP) | VAF 23/70 reads (33%) | called by muse, varscan2
- ADGRG3 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGPS | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ALDH5A1 | c.472C>T p.L158F | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- ANAPC1 | c.1274C>T p.S425L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2
- ANKRD24 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- APBB1IP | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- APOBR | c.1378G>A p.E460K (on ENST00000431282; = p.E469K on NM_018690.4) | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- ARHGAP15 | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP15 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 144/351 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARSF | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ASB17 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASCC3 | c.5687A>T p.Q1896L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ATP13A1 | c.2764C>T p.P922S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCL11A | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCL2L14 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BDH1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- BPIFB2 | c.1149G>A p.G383= | Splice Region (SNP) | VAF 42/102 reads (41%) | called by muse, mutect2, varscan2
- BRINP1 | c.579+1G>A p.X193_splice | Splice Site (SNP) | VAF 56/78 reads (72%) | called by muse, mutect2, varscan2
- C16orf78 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- CACNA1D | c.2479G>A p.E827K (on ENST00000350061 / NM_001128840.3; = p.E847K on NM_000720.4) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC158 | c.454C>T p.H152Y | Missense Mutation (SNP) | VAF 61/75 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- CCDC85A | c.1567C>T p.L523F | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- CCNB3 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- CCP110 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD1A | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 88/114 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD80 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- CDR1 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 154/414 reads (37%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CFI | c.1673T>C p.V558A | Missense Mutation (SNP) | VAF 127/182 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CHD7 | c.6208C>T p.H2070Y | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- CHRNA5 | c.1330C>T p.L444F | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CHRNA9 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 83/248 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLTRN | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CMYA5 | c.10279C>G p.L3427V | Missense Mutation (SNP) | VAF 63/112 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CNGB1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL11A2 | c.3356C>T p.P1119L (on ENST00000341947 / NM_080680.3; = p.P1012L on NM_080679.2) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- COL12A1 | c.4574C>T p.P1525L | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT tolerated (0.16); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- COL22A1 | c.2812G>A p.A938T | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL4A4 | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A6 | c.690G>A p.K230= | Splice Region (SNP) | VAF 178/387 reads (46%) | called by muse, mutect2, varscan2
- COL8A2 | c.1885A>G p.K629E | Missense Mutation (SNP) | VAF 72/127 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- COL9A2 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD1 | c.7690C>T p.Q2564* (on ENST00000520002; = p.Q2563* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2
- CUL4A | c.2254C>T p.P752S (on ENST00000375440 / NM_001008895.4; = p.P652S on NM_003589.3) | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP39A1 | c.1388T>G p.I463S | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- CYP4F2 | c.473A>G p.N158S | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.41); called by muse, varscan2
- DAB1 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DAO | c.55A>C p.I19L | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- DAZAP1 | c.71-1G>C p.X24_splice | Splice Site (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- DCC | c.3778C>T p.Q1260* | Nonsense Mutation (SNP) | VAF 53/140 reads (38%) | called by muse, mutect2, varscan2
- DEF8 | c.395C>T p.S132F (on ENST00000268676 / NM_207514.3; = p.S71F on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- DENND2C | c.1529C>T p.P510L (on ENST00000393274 / NM_001256404.2; = p.P453L on NM_198459.4) | Missense Mutation (SNP) | VAF 92/139 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DGKK | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DLG2 | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- DLGAP2 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DNAH7 | c.9028C>T p.L3010F | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DNAH8 | c.11405G>A p.W3802* | Nonsense Mutation (SNP) | VAF 135/221 reads (61%) | called by muse, mutect2, varscan2
- DOC2A | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- DOCK11 | c.4237T>A p.S1413T | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- DOT1L | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- DOT1L | c.1854G>T p.K618N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DSCAM | c.3668C>A p.T1223N | Missense Mutation (SNP) | VAF 111/282 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- ECHDC2 | c.859C>T p.P287S (on ENST00000371522 / NM_001198961.2; = p.P256S on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EDN3 | c.712C>T p.P238S (on ENST00000337938 / NM_001302455.2; = p.P224S on NM_207033.3) | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- EGF | c.2316G>A p.M772I | Missense Mutation (SNP) | VAF 104/140 reads (74%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ELL2 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- EPB41 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- EPB41L1 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA4 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 36/164 reads (22%) | called by muse, mutect2, varscan2
- EPHB6 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 95/254 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- EPHB6 | c.2866G>A p.A956T | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- EPPK1 | c.5614A>G p.T1872A | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERO1B | c.269G>A p.C90Y | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ERV3-1 | c.608C>T p.T203I | Missense Mutation (SNP) | VAF 108/259 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXD1 | c.959G>A p.R320K | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXPH5 | c.3293G>A p.R1098K | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FAM126A | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBN3 | c.7889G>C p.G2630A | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, varscan2
- FBXO40 | c.890G>A p.R297K | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FNBP4 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 45/93 reads (48%) | called by muse, mutect2, varscan2
- FNDC3A | c.3554C>T p.S1185F (on ENST00000492622 / NM_001079673.2; = p.S1129F on NM_014923.5) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FNDC7 | c.783A>T p.E261D | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- FNDC7 | c.784T>C p.Y262H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOXS1 | c.205A>G p.N69D | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FPR2 | c.502A>T p.T168S | Missense Mutation (SNP) | VAF 57/82 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FRMPD2 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- GABRA6 | c.481G>T p.V161F | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- GAST | c.224A>T p.K75M | Missense Mutation (SNP) | VAF 58/91 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GATA1 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GRIN2B | c.2671A>C p.M891L | Missense Mutation (SNP) | VAF 100/260 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GRM1 | c.78A>T p.K26N | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM5 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- GTPBP3 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- GUCY2D | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HAVCR1 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXD3 | c.1166A>G p.Y389C | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HPX | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HRH1 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- HSPB7 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.485); called by muse, mutect2
- HTR2C | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 80/221 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HYDIN | c.11743G>T p.D3915Y | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.3); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- HYDIN | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- IGFBP3 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IGHG2 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- IGHG4 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- IL1RAPL2 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 87/235 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IMPG1 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 55/81 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- INHBA | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- KBTBD12 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KCNJ11 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- KLHL23 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 74/136 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- KPNA6 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- KRT1 | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT5 | c.1751C>T p.S584F | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- KRT77 | c.1361G>A p.G454E | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- LAMA3 | c.9203G>A p.W3068* (on ENST00000313654 / NM_198129.4; = p.W1459* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- LARP4B | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- LILRB1 | c.334G>A p.E112K (on ENST00000427581; = p.E76K on NM_006669.6) | Missense Mutation (SNP) | VAF 83/205 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LINGO2 | c.1003A>G p.T335A | Missense Mutation (SNP) | VAF 45/63 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- LRG1 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRP2 | c.6235G>A p.E2079K | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- MAGEC2 | c.833G>A p.W278* | Nonsense Mutation (SNP) | VAF 64/270 reads (24%) | called by muse, mutect2, varscan2
- MAP2K3 | c.157G>A p.G53R (on ENST00000342679 / NM_145109.3; = p.G24R on NM_002756.4) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- MAP7D3 | c.417G>A p.K139= | Splice Region (SNP) | VAF 30/181 reads (17%) | called by muse, mutect2, varscan2
- MAPK15 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPK8IP2 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- MARK1 | c.2224T>G p.C742G | Missense Mutation (SNP) | VAF 92/126 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MECOM | c.50-1G>A p.X17_splice (on ENST00000468789 / NM_001105078.4; = p.X205_splice on NM_004991.4) | Splice Site (SNP) | VAF 38/127 reads (30%) | called by muse, mutect2, varscan2
- METTL21C | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM | c.5426T>A p.V1809D | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MORC1 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MPEG1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 96/258 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- MROH7 | c.1153G>A p.V385M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MROH7 | c.2245G>A p.G749S | Missense Mutation (SNP) | VAF 56/243 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- MROH7 | c.2796G>A p.W932* | Nonsense Mutation (SNP) | VAF 53/89 reads (60%) | called by muse, mutect2, varscan2
- MTMR4 | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.65); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- MUC16 | c.25247C>T p.S8416F | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- MUC16 | c.12902C>T p.T4301I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MUC17 | c.3344G>A p.S1115N | Missense Mutation (SNP) | VAF 332/1262 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- MUC17 | c.3469G>A p.E1157K | Missense Mutation (SNP) | VAF 362/1227 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- MYH15 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MYH7 | c.3934C>A p.L1312M | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MYO16 | c.1629G>C p.K543N | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MYO16 | c.3248C>T p.S1083F | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- MYO3B | c.3814G>A p.D1272N | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYOM3 | c.843T>G p.F281L | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- NAV3 | c.4576G>A p.E1526K | Missense Mutation (SNP) | VAF 56/78 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, varscan2
- NBAS | c.855_863del p.Q285_N288delinsH | In Frame Del (DEL) | VAF 62/105 reads (59%) | called by mutect2, pindel, varscan2
- NBEAL2 | c.6133C>T p.P2045S | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- NEU4 | c.908C>T p.P303L (on ENST00000391969 / NM_001167602.3; = p.P315L on NM_080741.4) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- NKAP | c.584A>T p.K195I | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- NLRC3 | c.3147G>A p.M1049I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.245); called by muse, mutect2
- NLRP5 | c.3293G>A p.R1098K | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.041); called by muse, varscan2
- NONO | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- NPHP1 | c.1145C>T p.S382L (on ENST00000393272 / NM_207181.4; = p.S383L on NM_000272.5) | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- NPHS1 | c.609G>A p.R203= | Splice Region (SNP) | VAF 40/55 reads (73%) | called by muse, mutect2, varscan2
- NRIP3 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NT5DC2 | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- NYAP1 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- OCIAD1 | c.59-1G>A p.X20_splice | Splice Site (SNP) | VAF 22/81 reads (27%) | called by muse, mutect2, varscan2
- OGA | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OR4C12 | c.74C>A p.T25K | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR7E24 | c.297G>A p.M99I | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- OTOP1 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OVCH1 | c.3130G>A p.G1044R | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- PCDH12 | c.2609C>T p.P870L | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHA10 | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 70/138 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHAC1 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.262); called by muse, mutect2
- PCLO | c.7582G>A p.D2528N | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- PCNX2 | c.2473G>A p.D825N | Missense Mutation (SNP) | VAF 64/81 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE3B | c.2209C>T p.H737Y | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PEAR1 | c.632G>A p.R211K | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHF6 | c.131A>G p.K44R | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PIK3C2G | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PITPNB | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- PKHD1L1 | c.4876G>A p.D1626N | Missense Mutation (SNP) | VAF 126/323 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLCB4 | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- PLXND1 | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- PNPLA5 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- PON3 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PPME1 | c.488T>C p.V163A | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- PPP1R3F | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- PPP1R9A | c.267del p.G91Vfs*10 | Frame Shift Del (DEL) | VAF 29/86 reads (34%) | called by mutect2, pindel, varscan2
- PRB2 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 192/692 reads (28%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.483); called by muse, varscan2
- PRB2 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 219/646 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, varscan2
- PRDM2 | c.4451C>T p.S1484F | Missense Mutation (SNP) | VAF 224/407 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PREX2 | c.4504G>A p.A1502T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PRKCB | c.1063A>G p.K355E | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- PRX | c.4331A>G p.E1444G | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTGDR | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTH1R | c.1767G>A p.W589* | Nonsense Mutation (SNP) | VAF 60/172 reads (35%) | called by muse, mutect2, varscan2
- PTPN22 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PTPN4 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RAD23A | c.270G>C p.E90D | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RASAL1 | c.1068+2T>A p.X356_splice | Splice Site (SNP) | VAF 68/110 reads (62%) | called by muse, mutect2, varscan2
- RASAL1 | c.1068+1G>A p.X356_splice | Splice Site (SNP) | VAF 68/111 reads (61%) | called by muse, mutect2, varscan2
- RASAL3 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- RASGRP2 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBMS3 | c.996G>A p.M332I | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RFX1 | c.1457C>T p.S486F | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RP1L1 | c.7094G>A p.G2365E | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- RSPH10B | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- RSPH10B2 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- RYR2 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 47/64 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- RYR3 | c.6857C>T p.S2286L (on ENST00000389232; = p.S2287L on NM_001036.6) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- SBF2 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SCN7A | c.4776G>A p.M1592I | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCNN1G | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SDK1 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SEMA3D | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 122/349 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERP2 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SF3B4 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SGCZ | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- SLC12A1 | c.2759G>A p.G920E | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC29A3 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLCO6A1 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SMAP2 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SP100 | c.2575C>T p.Q859* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- SPPL3 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SRCAP | c.7438C>T p.H2480Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- STAG2 | c.3667G>A p.E1223K | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- STK36 | c.3133C>T p.P1045S | Missense Mutation (SNP) | VAF 64/233 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SWAP70 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SYT12 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TCERG1L | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TCTE1 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TENM1 | c.4213C>T p.H1405Y | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- TEX15 | c.6311A>C p.Q2104P (on ENST00000256246; = p.Q2487P on NM_001350162.2) | Missense Mutation (SNP) | VAF 61/112 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- TEX37 | c.537C>A p.Y179* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- TFF1 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TM6SF1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TMEM51 | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 113/175 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TMPRSS6 | c.1711G>A p.G571R | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNFAIP3 | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- TNIK | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRANK1 | c.7204A>T p.I2402F | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- TRAV9-1 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRMT2B | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRPV5 | c.1766G>A p.R589K | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- TRPV6 | c.1532G>A p.G511E | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC5 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- TTLL4 | c.1297C>T p.H433Y | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTPAL | c.548T>A p.I183N | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- URM1 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT tolerated (0.16); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- XIRP1 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- YTHDC2 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZCCHC24 | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZDHHC23 | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 76/151 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZEB1 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFHX3 | c.8086G>A p.E2696K | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFPM2 | c.435G>T p.Q145H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- ZFPM2 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- ZNF366 | c.1123C>A p.P375T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF449 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZNF560 | c.1420G>A p.G474S | Missense Mutation (SNP) | VAF 118/288 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ZSCAN10 | c.418G>A p.G140R (on ENST00000252463; = p.G195R on NM_032805.3) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZZEF1 | c.760G>C p.A254P | Missense Mutation (SNP) | VAF 63/98 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- ACKR3 | c.96G>A p.V32= | Silent (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- ACO2 | c.792C>T p.I264= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs748474998; called by muse, mutect2, varscan2
- ACSM2B | c.1353T>C p.D451= | Silent (SNP) | VAF 48/327 reads (15%) | catalogued as rs184205149, COSV100312514; called by muse, mutect2, varscan2
- ADAMTS18 | c.1134G>A p.K378= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV51423451; called by muse, mutect2, varscan2
- ADAMTS6 | c.2712C>T p.F904= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as COSV58683222; called by muse, mutect2, varscan2
- AFG3L2 | c.570C>T p.V190= | Silent (SNP) | VAF 67/147 reads (46%) | catalogued as rs756146861; called by muse, mutect2, varscan2
- AGBL2 | c.1047C>A p.R349= | Silent (SNP) | VAF 39/189 reads (21%) | called by muse, mutect2, varscan2
- AL121899.2 | c.267G>A p.T89= | Silent (SNP) | VAF 83/221 reads (38%) | catalogued as rs753938291, COSV67350717; called by muse, mutect2, varscan2
- AL645922.1 | c.2289C>T p.I763= | Silent (SNP) | VAF 108/213 reads (51%) | catalogued as rs113410938, COSV54960296; called by muse, mutect2, varscan2
- ALMS1 | c.11385C>T p.G3795= | Silent (SNP) | VAF 51/89 reads (57%) | called by muse, mutect2, varscan2
- AMER3 | c.207G>A p.G69= | Silent (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- AMFR | c.1653C>T p.F551= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs778922910, COSV51922739; called by muse, mutect2, varscan2
- AMTN | c.501C>T p.T167= | Silent (SNP) | VAF 23/35 reads (66%) | called by muse, mutect2, varscan2
- ANO1 | c.1128C>T p.I376= | Silent (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- ASAH2 | c.405C>T p.T135= | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as rs745363908; called by muse, mutect2, varscan2
- ASTN2 | c.1668G>A p.Q556= (on ENST00000313400 / NM_001365069.1; = p.Q505= on NM_014010.5) | Silent (SNP) | VAF 37/49 reads (76%) | called by muse, mutect2, varscan2
- ATP13A1 | c.3090C>T p.F1030= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as rs770238768; called by muse, mutect2, varscan2
- ATP6V1G3 | c.99G>A p.L33= | Silent (SNP) | VAF 48/68 reads (71%) | catalogued as COSV99811108; called by muse, mutect2, varscan2
- B3GALT5 | c.906C>T p.S302= | Silent (SNP) | VAF 43/84 reads (51%) | called by muse, mutect2, varscan2
- BICRA | c.3252C>T p.F1084= | Silent (SNP) | VAF 37/48 reads (77%) | catalogued as COSV67606484; called by muse, mutect2, varscan2
- BRINP3 | c.903G>A p.E301= | Silent (SNP) | VAF 48/60 reads (80%) | called by muse, mutect2, varscan2
- CA10 | c.834C>T p.I278= | Silent (SNP) | VAF 45/60 reads (75%) | catalogued as COSV53337218, COSV53350742; called by muse, mutect2, varscan2
- CACNA1B | c.4833C>T p.F1611= | Silent (SNP) | VAF 65/98 reads (66%) | catalogued as COSV99500563; called by muse, mutect2, varscan2
- CACNA1G | c.6111G>A p.R2037= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as COSV100661300; called by muse, mutect2, varscan2
- CACNA1I | c.2581C>T p.L861= | Silent (SNP) | VAF 34/102 reads (33%) | called by muse, mutect2, varscan2
- CCDC120 | c.1128C>T p.S376= | Silent (SNP) | VAF 17/29 reads (59%) | called by muse, mutect2, varscan2
- CCDC7 | c.4098A>G p.K1366= | Silent (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- CCN1 | c.675A>G p.Q225= | Silent (SNP) | VAF 51/91 reads (56%) | called by muse, mutect2, varscan2
- CDH23 | c.2127C>T p.I709= | Silent (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- CEACAM3 | c.480C>T p.V160= | Silent (SNP) | VAF 116/171 reads (68%) | called by muse, mutect2, varscan2
- CELSR3 | c.6930A>G p.E2310= | Silent (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- CFHR5 | c.1119G>A p.G373= | Silent (SNP) | VAF 29/32 reads (91%) | catalogued as COSV56819664; called by muse, mutect2, varscan2
- CFTR | c.600C>T p.F200= | Silent (SNP) | VAF 101/284 reads (36%) | catalogued as rs753492211, COSV50040466; called by muse, mutect2, varscan2
- CHD5 | c.5793C>T p.F1931= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV52411190; called by muse, mutect2
- CIP2A | c.2190C>T p.S730= | Silent (SNP) | VAF 56/102 reads (55%) | catalogued as rs146232264; called by muse, mutect2, varscan2
- CLRN3 | c.414C>T p.S138= | Silent (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- CLVS1 | c.504C>T p.V168= | Silent (SNP) | VAF 50/132 reads (38%) | catalogued as COSV100370131; called by muse, mutect2, varscan2
- CNTN5 | c.1071G>A p.P357= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as rs769061773; called by muse, mutect2, varscan2
- CNTN6 | c.2433C>T p.L811= | Silent (SNP) | VAF 112/281 reads (40%) | called by muse, mutect2, varscan2
- COG4 | c.1089C>T p.V363= | Silent (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- COL21A1 | c.456G>A p.K152= | Silent (SNP) | VAF 26/103 reads (25%) | called by muse, mutect2, varscan2
- COL2A1 | c.3207C>G p.A1069= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs777096609; called by mutect2, varscan2
- COL8A2 | c.1884C>G p.V628= | Silent (SNP) | VAF 72/126 reads (57%) | called by muse, mutect2, varscan2
- CPS1 | c.3825C>T p.F1275= | Silent (SNP) | VAF 48/178 reads (27%) | catalogued as COSV51811245, COSV51813188; called by muse, mutect2, varscan2
- CRYBB1 | c.264C>T p.F88= | Silent (SNP) | VAF 61/146 reads (42%) | catalogued as rs779476968, COSV53233294; called by muse, mutect2, varscan2
- CSMD2 | c.6594C>T p.F2198= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV53910970; called by muse, mutect2, varscan2
- CSMD2 | c.2958C>T p.F986= | Silent (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- CTDNEP1 | c.654C>T p.L218= | Silent (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- CTRL | c.666G>A p.K222= | Silent (SNP) | VAF 37/100 reads (37%) | called by muse, mutect2, varscan2
- CUZD1 | c.690C>T p.G230= | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as rs1456381591; called by muse, mutect2, varscan2
- CYP4F11 | c.858C>T p.F286= | Silent (SNP) | VAF 57/197 reads (29%) | catalogued as COSV56126107; called by muse, mutect2, varscan2
- CYP4F3 | c.306C>T p.F102= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as rs61734302; called by muse, mutect2, varscan2
- DCTN1 | c.3660C>T p.P1220= | Silent (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- DLC1 | c.2484C>T p.S828= (on ENST00000276297 / NM_001348081.2; = p.S391= on NM_006094.5) | Silent (SNP) | VAF 69/191 reads (36%) | called by muse, mutect2, varscan2
- DNAH8 | c.1347G>A p.G449= | Silent (SNP) | VAF 75/132 reads (57%) | called by muse, mutect2, varscan2
- DOCK2 | c.1911G>A p.L637= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV56952167; called by muse, mutect2, varscan2
- DOCK8 | c.1611G>A p.R537= | Silent (SNP) | VAF 24/47 reads (51%) | called by muse, mutect2, varscan2
- DOCK9 | c.3402C>T p.I1134= (on ENST00000376460 / NM_001366676.2; = p.I1135= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/128 reads (35%) | catalogued as rs201631225; called by muse, mutect2, varscan2
- DSCAM | c.4764G>A p.T1588= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs529976538; called by muse, mutect2, varscan2
- DSEL | c.403C>T p.L135= | Silent (SNP) | VAF 26/107 reads (24%) | called by muse, mutect2, varscan2
- DYSF | c.3267C>T p.F1089= | Silent (SNP) | VAF 82/162 reads (51%) | catalogued as rs945602962; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ECT2L | c.921G>A p.V307= | Silent (SNP) | VAF 57/69 reads (83%) | called by muse, mutect2, varscan2
- ELMO1 | c.21C>T p.I7= | Silent (SNP) | VAF 91/256 reads (36%) | catalogued as rs758092021, COSV60302447; called by muse, mutect2, varscan2
- EMP1 | c.198C>T p.A66= | Silent (SNP) | VAF 109/261 reads (42%) | catalogued as rs1248502433; called by muse, mutect2, varscan2
- ESX1 | c.1173C>T p.I391= | Silent (SNP) | VAF 29/63 reads (46%) | called by muse, varscan2
- F2R | c.1017C>T p.F339= | Silent (SNP) | VAF 46/92 reads (50%) | called by muse, mutect2, varscan2
- FAM135B | c.3519C>T p.F1173= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as COSV52724035; called by muse, mutect2, varscan2
- FAM171A1 | c.273G>A p.S91= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as rs372916877; called by muse, mutect2, varscan2
- FAM214A | c.72C>T p.A24= | Silent (SNP) | VAF 27/56 reads (48%) | called by muse, mutect2, varscan2
- FAM9B | c.339C>T p.I113= | Silent (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- FBN2 | c.4584G>A p.G1528= | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as rs1554121089; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBXW7 | c.1266T>A p.G422= (on ENST00000281708 / NM_001349798.2; = p.G342= on NM_018315.5) | Silent (SNP) | VAF 138/190 reads (73%) | catalogued as rs751939123; called by muse, mutect2, varscan2
- FLG2 | c.1317C>T p.S439= | Silent (SNP) | VAF 196/252 reads (78%) | catalogued as COSV66167343; called by muse, mutect2, varscan2
- FMO1 | c.1329C>T p.I443= | Silent (SNP) | VAF 76/102 reads (75%) | catalogued as COSV61445800; called by muse, mutect2, varscan2
- FNDC5 | c.225G>A p.R75= | Silent (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- FOXN1 | c.1749T>C p.P583= | Silent (SNP) | VAF 29/47 reads (62%) | called by muse, mutect2, varscan2
- GAS2L2 | c.2151G>A p.R717= | Silent (SNP) | VAF 68/97 reads (70%) | called by muse, mutect2, varscan2
- GAS2L2 | c.957C>T p.P319= | Silent (SNP) | VAF 68/97 reads (70%) | called by muse, mutect2, varscan2
- GATA1 | c.420G>A p.R140= | Silent (SNP) | VAF 51/108 reads (47%) | called by muse, mutect2, varscan2
- GCSAML | c.246G>A p.L82= | Silent (SNP) | VAF 83/106 reads (78%) | called by muse, mutect2, varscan2
- GIMAP1 | c.459G>A p.R153= | Silent (SNP) | VAF 44/113 reads (39%) | called by muse, mutect2, varscan2
- GLI2 | c.1287G>A p.K429= (on ENST00000361492 / NM_001374353.1; = p.K446= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- GLRB | c.483C>T p.I161= | Silent (SNP) | VAF 102/137 reads (74%) | catalogued as COSV52421886; called by muse, mutect2, varscan2
- GLT1D1 | c.717G>A p.V239= (on ENST00000442111 / NM_001366889.1; = p.V159= on NM_144669.3) | Silent (SNP) | VAF 37/50 reads (74%) | catalogued as COSV99897304; called by muse, mutect2, varscan2
- GPC6 | c.783C>T p.P261= | Silent (SNP) | VAF 77/200 reads (39%) | catalogued as rs1486674925; called by muse, mutect2, varscan2
- GRIA4 | c.1761C>T p.D587= | Silent (SNP) | VAF 37/81 reads (46%) | called by muse, mutect2, varscan2
- GRM4 | c.1350C>T p.I450= | Silent (SNP) | VAF 34/58 reads (59%) | catalogued as rs1218981364, COSV65211849; called by muse, mutect2, varscan2
- GRM4 | c.489C>T p.I163= | Silent (SNP) | VAF 46/78 reads (59%) | catalogued as COSV65219379; called by muse, mutect2, varscan2
- HAS1 | c.1258C>T p.L420= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as COSV55789843; called by muse, mutect2, varscan2
- HDGFL1 | c.324G>A p.E108= | Silent (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- HOXA13 | c.774C>T p.L258= | Silent (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- HS3ST4 | c.1370G>A p.*457= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV58810611; called by muse, mutect2, varscan2
- HUWE1 | c.12036C>T p.L4012= | Silent (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- HYDIN | c.5673C>T p.P1891= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs1276040367; called by mutect2, varscan2
- IFT140 | c.3045C>T p.H1015= | Silent (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- IGFL1 | c.102G>A p.L34= | Silent (SNP) | VAF 77/111 reads (69%) | called by muse, mutect2, varscan2
- IL18R1 | c.1069C>T p.L357= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV52126517; called by muse, mutect2, varscan2
- IL1R2 | c.144G>A p.L48= | Silent (SNP) | VAF 58/253 reads (23%) | catalogued as COSV100208039; called by muse, mutect2, varscan2
- IRX6 | c.591C>T p.F197= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV51859386; called by muse, mutect2, varscan2
- KCNA2 | c.546G>A p.L182= | Silent (SNP) | VAF 33/138 reads (24%) | called by muse, mutect2, varscan2
- KCNB2 | c.942C>T p.L314= | Silent (SNP) | VAF 49/117 reads (42%) | catalogued as rs145537672, COSV73049623; called by muse, mutect2, varscan2
- KCNC3 | c.945C>T p.F315= | Silent (SNP) | VAF 27/39 reads (69%) | called by muse, mutect2, varscan2
- KCND2 | c.51C>T p.I17= | Silent (SNP) | VAF 112/330 reads (34%) | catalogued as rs751910698, COSV58600385; called by muse, mutect2, varscan2
- KCNK16 | c.129C>T p.S43= | Silent (SNP) | VAF 43/71 reads (61%) | catalogued as rs753644738, COSV64678879; called by muse, mutect2, varscan2
- KCNMB1 | c.423G>A p.G141= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV51131299; called by muse, mutect2, varscan2
- KIF21B | c.1173G>A p.E391= | Silent (SNP) | VAF 53/70 reads (76%) | called by muse, mutect2, varscan2
- KL | c.2835G>A p.R945= | Silent (SNP) | VAF 43/148 reads (29%) | catalogued as COSV66310129; called by muse, mutect2, varscan2
- KNSTRN | c.60A>G p.T20= | Silent (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- KRT77 | c.1362G>T p.G454= | Silent (SNP) | VAF 37/52 reads (71%) | called by muse, mutect2, varscan2
- LAMA3 | c.9252G>A p.V3084= (on ENST00000313654 / NM_198129.4; = p.V1475= on NM_000227.6) | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as rs267605131; called by muse, mutect2, varscan2
- LAMB2 | c.2028A>C p.I676= | Silent (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- LCT | c.2856C>T p.A952= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as rs1445901469, COSV51551470; called by muse, mutect2, varscan2
- LILRA4 | c.1213C>T p.L405= | Silent (SNP) | VAF 50/135 reads (37%) | called by muse, mutect2, varscan2
- LMF1 | c.339C>T p.I113= | Silent (SNP) | VAF 13/31 reads (42%) | called by muse, varscan2
- LRRC66 | c.1923C>G p.S641= | Silent (SNP) | VAF 46/64 reads (72%) | catalogued as rs780378961, COSV58635207; called by muse, mutect2, varscan2
- LUZP2 | c.481C>T p.L161= | Silent (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
- MACROH2A1 | c.939C>T p.S313= (on ENST00000510038; = p.S312= on NM_004893.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/139 reads (44%) | called by muse, mutect2, varscan2
- MAGEC2 | c.51G>A p.P17= | Silent (SNP) | VAF 94/346 reads (27%) | catalogued as rs778766259, COSV55998994, COSV56002050; called by muse, mutect2, varscan2
- MAML3 | c.1767C>T p.S589= | Silent (SNP) | VAF 322/408 reads (79%) | called by muse, mutect2, varscan2
- MAP3K6 | c.1887G>A p.A629= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV62890092; called by muse, mutect2, varscan2
- MAPK15 | c.1617G>A p.L539= | Silent (SNP) | VAF 27/83 reads (33%) | called by muse, mutect2, varscan2
- MAPK4 | c.138C>T p.V46= | Silent (SNP) | VAF 48/128 reads (38%) | catalogued as rs763775905; called by muse, mutect2, varscan2
- MAPK8IP2 | c.420C>T p.T140= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV50496897; called by muse, mutect2, varscan2
- MAT1A | c.342C>T p.S114= | Silent (SNP) | VAF 62/118 reads (53%) | called by muse, mutect2, varscan2
- MDN1 | c.8095C>T p.L2699= | Silent (SNP) | VAF 29/47 reads (62%) | catalogued as rs767387175; called by muse, mutect2, varscan2
- MIA3 | c.3663G>A p.K1221= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as rs1350759157; called by muse, mutect2, varscan2
- MLC1 | c.651G>A p.L217= | Silent (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- MLIP | c.981G>A p.Q327= | Silent (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.369C>T p.S123= | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as rs756868732, COSV57106770; called by muse, mutect2, varscan2
- MS4A14 | c.144C>T p.T48= | Silent (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- MSLNL | c.1203T>A p.A401= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- MUC16 | c.19362G>A p.A6454= | Silent (SNP) | VAF 84/214 reads (39%) | catalogued as rs1040557669; called by muse, varscan2
- MUC16 | c.14817C>T p.S4939= | Silent (SNP) | VAF 55/168 reads (33%) | called by muse, mutect2, varscan2
- MYL3 | c.402G>A p.V134= | Silent (SNP) | VAF 68/161 reads (42%) | called by muse, mutect2, varscan2
- MYO3B | c.3847C>T p.L1283= | Silent (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- MYOCD | c.2178C>T p.A726= | Silent (SNP) | VAF 34/57 reads (60%) | catalogued as rs770762459; called by muse, mutect2, varscan2
- NAMPT | c.240C>T p.I80= | Silent (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
- NANP | c.294C>T p.F98= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as COSV59160283; called by muse, mutect2, varscan2
- NCAPD2 | c.1629C>T p.F543= | Silent (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- NDRG4 | c.384C>T p.P128= (on ENST00000570248 / NM_001378344.1; = p.P160= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs564622381; called by muse, mutect2, varscan2
- NEB | c.4914G>A p.K1638= | Silent (SNP) | VAF 42/197 reads (21%) | catalogued as COSV50987313; called by muse, mutect2, varscan2
- NECAB2 | c.756C>T p.I252= | Silent (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- NEUROD4 | c.399G>A p.R133= | Silent (SNP) | VAF 49/81 reads (60%) | catalogued as COSV54470715; called by muse, mutect2, varscan2
- NEXMIF | c.1419C>T p.S473= | Silent (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- NLGN4X | c.1584G>A p.T528= | Silent (SNP) | VAF 43/131 reads (33%) | catalogued as rs746041687; called by muse, mutect2, varscan2
- NLRP10 | c.1401C>T p.I467= | Silent (SNP) | VAF 88/191 reads (46%) | called by muse, mutect2, varscan2
- NLRP4 | c.876G>A p.T292= | Silent (SNP) | VAF 60/86 reads (70%) | catalogued as rs368289644, COSV100016064; called by muse, mutect2, varscan2
- NOS3 | c.1047C>T p.P349= | Silent (SNP) | VAF 95/291 reads (33%) | catalogued as rs373924769; called by muse, mutect2, varscan2
- NPSR1 | c.660C>T p.F220= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as rs776613439, COSV62202224; called by muse, mutect2, varscan2
- NRAP | c.1209C>T p.T403= | Silent (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- NRXN2 | c.2844C>T p.T948= | Silent (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- OBSCN | c.4495C>T p.L1499= | Silent (SNP) | VAF 55/72 reads (76%) | called by muse, mutect2, varscan2
- OBSCN | c.12189C>T p.V4063= | Silent (SNP) | VAF 55/75 reads (73%) | called by muse, mutect2, varscan2
- OR10G8 | c.717C>T p.T239= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as COSV70908535; called by muse, mutect2, varscan2
- OR10H1 | c.645C>T p.I215= | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as rs1181036170; called by muse, varscan2
- OR10H2 | c.213C>T p.I71= | Silent (SNP) | VAF 24/177 reads (14%) | catalogued as COSV59945592; called by muse, varscan2
- OR10H2 | c.375C>T p.A125= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as rs751123354, COSV100008790; called by muse, mutect2, varscan2
- OR13F1 | c.414G>A p.R138= | Silent (SNP) | VAF 56/73 reads (77%) | catalogued as COSV58252749; called by muse, mutect2, varscan2
- OR4K14 | c.489C>T p.F163= | Silent (SNP) | VAF 43/56 reads (77%) | called by muse, mutect2, varscan2
- OR4S2 | c.657C>T p.I219= | Silent (SNP) | VAF 71/87 reads (82%) | called by muse, mutect2, varscan2
- OR51D1 | c.423C>T p.H141= | Silent (SNP) | VAF 53/145 reads (37%) | catalogued as COSV62914178; called by muse, mutect2, varscan2
- OR8G5 | c.186C>T p.F62= | Silent (SNP) | VAF 52/149 reads (35%) | catalogued as rs1213996294, COSV100422511; called by muse, mutect2
- OR8H3 | c.375G>A p.A125= | Silent (SNP) | VAF 153/370 reads (41%) | catalogued as COSV57909400, COSV57909630; called by muse, mutect2, varscan2
- OVCH1 | c.1509C>T p.F503= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- PAPPA2 | c.2922C>T p.F974= | Silent (SNP) | VAF 178/233 reads (76%) | catalogued as COSV62798202; called by muse, mutect2, varscan2
- PCDHA4 | c.2340G>A p.R780= | Silent (SNP) | VAF 51/121 reads (42%) | catalogued as COSV63544726; called by muse, mutect2, varscan2
- PCDHA9 | c.270C>T p.I90= | Silent (SNP) | VAF 75/270 reads (28%) | catalogued as rs1373306767, COSV65325571; called by muse, mutect2, varscan2
- PCDHB4 | c.396C>T p.F132= | Silent (SNP) | VAF 37/63 reads (59%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.1980C>T p.F660= | Silent (SNP) | VAF 63/148 reads (43%) | catalogued as COSV53918095; called by muse, mutect2, varscan2
- PCLO | c.1279C>T p.L427= | Silent (SNP) | VAF 57/159 reads (36%) | called by muse, mutect2, varscan2
- PDE4DIP | c.4554G>A p.R1518= | Silent (SNP) | VAF 26/38 reads (68%) | called by muse, mutect2, varscan2
- PDPR | c.2370C>T p.Y790= | Silent (SNP) | VAF 37/201 reads (18%) | called by muse, mutect2, varscan2
- PLXNB1 | c.4221G>T p.L1407= | Silent (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- PLXNB2 | c.3951C>T p.Y1317= | Silent (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2
- PMPCB | c.675C>T p.D225= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as rs1368447034; called by muse, mutect2, varscan2
- POLA1 | c.4365C>T p.F1455= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as rs150514156, COSV100985126; called by muse, mutect2, varscan2
- POLB | c.816C>T p.F272= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs1268563119; called by muse, mutect2, varscan2
- POM121L12 | c.474C>T p.A158= | Silent (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- POSTN | c.1380C>T p.F460= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as rs748262613, COSV101123261; called by muse, mutect2, varscan2
- POTED | c.456C>T p.V152= | Silent (SNP) | VAF 56/68 reads (82%) | called by muse, mutect2, varscan2
- PPP2R2B | c.714C>T p.F238= (on ENST00000394409; = p.F304= on NM_181674.2) | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as rs755977610; called by muse, mutect2, varscan2
- PPP2R3B | c.465C>T p.F155= | Silent (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- PRAMEF10 | c.384C>T p.A128= | Silent (SNP) | VAF 55/306 reads (18%) | called by muse, mutect2, varscan2
- PREX2 | c.4731G>A p.A1577= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as rs756670148, COSV55752329; called by muse, mutect2, varscan2
- PRKCB | c.1062C>T p.G354= | Silent (SNP) | VAF 40/153 reads (26%) | called by muse, mutect2, varscan2
- PRKCZ | c.240C>T p.F80= | Silent (SNP) | VAF 42/70 reads (60%) | called by muse, mutect2, varscan2
- PRMT9 | c.1269C>T p.S423= | Silent (SNP) | VAF 32/32 reads (100%) | catalogued as COSV100482295; called by muse, mutect2, varscan2
- PSD4 | c.285C>T p.D95= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV55527286; called by muse, mutect2, varscan2
- PSG11 | c.495G>A p.V165= | Silent (SNP) | VAF 177/244 reads (73%) | called by muse, mutect2, varscan2
- PTCHD1 | c.2628C>T p.I876= | Silent (SNP) | VAF 65/137 reads (47%) | catalogued as rs747214128; called by muse, mutect2, varscan2
- PTPRT | c.2727G>A p.E909= | Silent (SNP) | VAF 104/260 reads (40%) | called by muse, mutect2, varscan2
- PTPRT | c.2253C>T p.I751= | Silent (SNP) | VAF 44/103 reads (43%) | catalogued as rs771479479, COSV61963962, COSV62011133; called by muse, mutect2, varscan2
- RASGRP2 | c.1212C>T p.P404= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs1214420438; called by muse, mutect2, varscan2
- RASSF4 | c.762G>A p.R254= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs1488066276; called by muse, mutect2, varscan2
- RGR | c.741C>T p.S247= | Silent (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
83 further variants in this file (0 protein-altering or splice-affecting, 62 silent, 21 other) are not listed here.
